Somatic mutation profile of tumor specimen TCGA-DJ-A1QF-01A (aliquot TCGA-DJ-A1QF-01A-12D-A14W-08) from TCGA case TCGA-DJ-A1QF, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage II; Age at diagnosis: 61.1 years (22,310 days).
Specimen TCGA-DJ-A1QF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d0160e4-d968-40d6-9b47-c4ae37b65ad2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A1QF-10A (Blood Derived Normal), aliquot TCGA-DJ-A1QF-10A-01D-A14W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/26a85b4b-b183-4a04-9429-1abec12b2f6f

The open-access MAF lists 13 somatic variants for this specimen: 4 protein-altering or splice-affecting, 9 silent.
By variant classification: Silent 9, Missense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- AFF2 | c.2849C>T p.T950I | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as rs1569557756, COSV53993867, COSV53994371; called by muse, mutect2
- PARPBP | c.730G>A p.D244N | Missense Mutation (SNP) | VAF 7/150 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.181); catalogued as COSV59674324; called by muse, mutect2
- STC2 | c.71G>C p.G24A | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as COSV54180398, COSV99438750; called by muse, mutect2, varscan2
- ANGPTL1 | c.459A>G p.Q153= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV52366828; called by muse, mutect2, varscan2
- DELE1 | c.357C>A p.S119= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as COSV52005368; called by muse, mutect2
- GALNT1 | c.1059G>A p.T353= | Silent (SNP) | VAF 9/181 reads (5%) | catalogued as rs1444044240, COSV52453080; called by muse, mutect2
- IFIT1B | c.1216T>C p.L406= | Silent (SNP) | VAF 38/104 reads (37%) | catalogued as rs1285086298, COSV65663522; called by muse, mutect2, varscan2
- KCTD3 | c.1801T>C p.L601= | Silent (SNP) | VAF 20/119 reads (17%) | catalogued as COSV52067640; called by muse, mutect2, varscan2
- MUC16 | c.12963T>C p.A4321= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV67473844; called by muse, mutect2, varscan2
- SMG1 | c.5475A>G p.Q1825= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as rs376900887; called by muse, mutect2
- SRPK2 | c.1278A>G p.T426= | Silent (SNP) | VAF 8/164 reads (5%) | catalogued as rs1453843216, COSV61961822; called by muse, mutect2
- WDR45B | c.519C>T p.S173= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV66408507; called by muse, mutect2, varscan2
